Somatic mutation profile of tumor specimen MMRF_2636_1_BM_CD138pos (aliquot MMRF_2636_1_BM_CD138pos_T1_KHS5U_L13316) from MMRF case MMRF_2636, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.4 years (20,974 days).
Specimen MMRF_2636_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 632076a0-04a2-4e08-8c07-8edf486af4e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2636_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2636_1_PB_WBC_C3_KHS5U_L13317; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0af40f9-d558-48d8-81b6-6f6d2ec90149

The open-access MAF lists 119 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 25, Silent 18, Intron 12, 3'Flank 5, 5'UTR 4, RNA 3, Splice Site 3, 5'Flank 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1475T>G | 3'UTR (SNP) | VAF 40/95 reads (42%) | catalogued as rs121913101, CM950478, CM950479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2B2 | c.2921C>T p.A974V (on ENST00000352432; = p.A940V on NM_001683.5) | Missense Mutation (SNP) | VAF 135/234 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as rs751257556; called by muse, mutect2, varscan2
- CNOT1 | c.4031A>G p.N1344S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752211632; called by muse, mutect2, varscan2
- IGLV3-1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 66/76 reads (87%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs189772470; called by muse, varscan2
- IGLV3-1 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 64/72 reads (89%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373323725; called by muse, varscan2
- KCNB1 | c.2024A>G p.N675S | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs1186529246; called by muse, mutect2, varscan2
- MUC16 | c.2002A>G p.T668A | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1471702842; called by muse, mutect2, varscan2
- NR6A1 | c.442-1G>C p.X148_splice (on ENST00000487099 / NM_033334.4; = p.X144_splice on NM_001489.5) | Splice Site (SNP) | VAF 84/180 reads (47%) | catalogued as COSV60631461; called by muse, mutect2, varscan2
- PTPRT | c.904del p.A302Pfs*21 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as COSV62008630; called by mutect2, pindel, varscan2
- TMEM134 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.658); catalogued as rs1165081566; called by muse, mutect2, varscan2
- ZAN | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs759611480, COSV100769961, COSV61811172; called by muse, mutect2, varscan2
- ZNF467 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57372967; called by muse, mutect2, varscan2
- ADAMTS19 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ADGRD2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2
- ADIPOR1 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ATAD5 | c.4405T>A p.F1469I | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BIRC6 | c.9580T>A p.S3194T | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- C21orf91 | c.35dup p.L12Ffs*3 | Frame Shift Ins (INS) | VAF 160/458 reads (35%) | called by mutect2, pindel, varscan2
- CACNA1E | c.538T>C p.F180L | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAMK1 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 118/248 reads (48%) | called by muse, mutect2, varscan2
- CARD9 | c.808-8C>G | Splice Region (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- CDK14 | c.904G>A p.V302I (on ENST00000380050 / NM_001287135.2; = p.V284I on NM_012395.3) | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CSPG5 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTC1 | c.2754A>T p.K918N | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DNAH17 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPHA6 | c.2596G>T p.V866F (on ENST00000389672 / NM_001080448.3; = p.V258F on NM_173655.4) | Missense Mutation (SNP) | VAF 147/223 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPOR | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- IGHV2-70D | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGHV2-70D | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, varscan2
- IGHV2-70D | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IPO9 | c.2947T>A p.Y983N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 37/465 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.357); called by muse, mutect2
- LARGE1 | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 39/39 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- LIG3 | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LRRN1 | c.1966T>C p.F656L | Missense Mutation (SNP) | VAF 165/311 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MKRN3 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- MYO1D | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFAF1 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5K1 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 193/596 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PIGN | c.1880T>G p.V627G | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PNPLA7 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RNF149 | c.780+2T>G p.X260_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- SLC4A7 | c.2400+1G>A p.X800_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- TANC2 | c.5239G>T p.V1747L | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2
- TEX13C | c.1661C>A p.P554H | Missense Mutation (SNP) | VAF 133/139 reads (96%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TLR1 | c.1903C>G p.L635V | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDFY3 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZAR1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, varscan2
- C11orf45 | c.45C>T p.T15= | Silent (SNP) | VAF 66/164 reads (40%) | catalogued as COSV57967749; called by muse, mutect2, varscan2
- CARMIL3 | c.2572C>A p.R858= | Silent (SNP) | VAF 76/160 reads (48%) | called by muse, mutect2, varscan2
- CLSTN1 | c.585G>A p.Q195= (on ENST00000377298 / NM_001009566.3; = p.Q185= on NM_014944.4) | Silent (SNP) | VAF 76/168 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2052G>A p.R684= | Silent (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- COL6A3 | c.6177C>T p.G2059= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as COSV55115370; called by muse, mutect2, varscan2
- CTU2 | c.654C>T p.A218= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs768437983; called by muse, mutect2, varscan2
- FAM131A | c.861G>A p.A287= (on ENST00000310585; = p.A318= on NM_144635.5) | Silent (SNP) | VAF 107/151 reads (71%) | catalogued as rs756881641; called by muse, mutect2, varscan2
- HCN3 | c.1263C>T p.G421= | Silent (SNP) | VAF 69/112 reads (62%) | catalogued as rs1557949286; called by muse, mutect2, varscan2
- IGLL5 | c.79C>T p.L27= | Silent (SNP) | VAF 34/34 reads (100%) | catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, varscan2
- IPO9 | c.2946T>C p.D982= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- JMJD4 | c.1170C>T p.I390= | Silent (SNP) | VAF 172/304 reads (57%) | catalogued as rs749917670, COSV100248368; called by muse, mutect2, varscan2
- KHNYN | c.2025T>C p.S675= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as COSV52160140; called by muse, mutect2, varscan2
- KIF1A | c.1605C>T p.F535= | Silent (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- LAMA1 | c.6552C>T p.S2184= | Silent (SNP) | VAF 121/236 reads (51%) | catalogued as rs149288175; ClinVar: likely benign; called by muse, mutect2, varscan2
- OXSR1 | c.1428A>G p.G476= | Silent (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- RREB1 | c.4074C>T p.N1358= | Silent (SNP) | VAF 82/159 reads (52%) | called by muse, mutect2, varscan2
- SCRN1 | c.393C>T p.V131= | Silent (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- TMCO6 | c.18G>A p.Q6= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- ABCB5 | c.1707+8531C>T | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- BHLHA15 | chr7:98213079 T>G | 3'Flank (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2
- CALD1 | c.71+109A>C | Intron (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
- CD55 | c.980-31A>G | Intron (SNP) | VAF 181/307 reads (59%) | called by muse, mutect2, varscan2
- CDC34 | c.363-33G>A | Intron (SNP) | VAF 32/72 reads (44%) | catalogued as rs369453041; called by muse, mutect2, varscan2
- COL1A2 | c.3105+142C>G | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2
- DAAM1 | c.*391del | 3'UTR (DEL) | VAF 4/25 reads (16%) | catalogued as rs1264181007, COSV62837228; called by pindel, varscan2
- DNAH8 | c.11874+54T>C | Intron (SNP) | VAF 241/524 reads (46%) | called by muse, mutect2, varscan2
- DPY19L4 | chr8:94719760 G>A | 5'Flank (SNP) | VAF 16/40 reads (40%) | catalogued as rs1372205200; called by muse, mutect2, varscan2
- ELN | chr7:74068895 del C | 3'Flank (DEL) | VAF 44/112 reads (39%) | catalogued as rs1464827966; called by mutect2, pindel, varscan2
- ELN | chr7:74068896 C>A | 3'Flank (SNP) | VAF 48/99 reads (48%) | called by mutect2, varscan2
- ELOC | c.*63T>C | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- EPPK1 | c.*104T>C | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- FRG2B | c.*334A>C | 3'UTR (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- GABRG2 | c.-75T>C | 5'UTR (SNP) | VAF 115/242 reads (48%) | called by muse, mutect2, varscan2
- GFRA1 | c.*234G>A | 3'UTR (SNP) | VAF 22/88 reads (25%) | catalogued as rs1209720742; called by muse, mutect2, varscan2
- HPGD | c.*1269T>A | 3'UTR (SNP) | VAF 78/149 reads (52%) | called by muse, mutect2, varscan2
- HTR2C | c.*1517C>A | 3'UTR (SNP) | VAF 47/47 reads (100%) | called by muse, mutect2, varscan2
- KCNMB3P1 | n.2244del | RNA (DEL) | VAF 83/104 reads (80%) | catalogued as rs954597037; called by mutect2, varscan2
- LGR4 | c.-279C>T | 5'UTR (SNP) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- LURAP1L | c.-346T>G | 5'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- MAP6 | c.-373G>C | 5'UTR (SNP) | VAF 35/73 reads (48%) | catalogued as rs1001951903; called by muse, mutect2, varscan2
- MCRIP1 | c.-48-1522C>A | Intron (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- MST1L | n.1616T>A | RNA (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- MYORG | c.*2969C>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- NCK1 | c.*557A>C | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- NRG1 | chr8:32764591 T>G | 3'Flank (SNP) | VAF 23/35 reads (66%) | called by muse, mutect2, varscan2
- OSBPL8 | c.*632del | 3'UTR (DEL) | VAF 34/62 reads (55%) | catalogued as rs1404855250; called by mutect2, varscan2
- PAN2 | c.3282+52T>C | Intron (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- PARM1 | c.*2057G>C | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- PCLAF | c.*419T>G | 3'UTR (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- PGR | c.*3880dup | 3'UTR (INS) | VAF 26/60 reads (43%) | catalogued as rs934969377; called by mutect2, varscan2
- PLXNA4 | c.*4491A>C | 3'UTR (SNP) | VAF 93/197 reads (47%) | called by muse, mutect2, varscan2
- POLR1F | c.*1881C>A | 3'UTR (SNP) | VAF 40/88 reads (45%) | catalogued as rs902600151; called by muse, mutect2, varscan2
- PPP1R15B | c.*1141C>T | 3'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- PRKRA | c.235+82_235+83del | Intron (DEL) | VAF 18/64 reads (28%) | catalogued as rs1412578674; called by pindel, varscan2
- RABL2A | c.*16+388G>A | Intron (SNP) | VAF 292/644 reads (45%) | called by muse, mutect2, varscan2
- RIT2 | c.*237C>G | 3'UTR (SNP) | VAF 51/81 reads (63%) | called by muse, mutect2, varscan2
- RSPH9 | c.*62G>C | 3'UTR (SNP) | VAF 210/446 reads (47%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863561 C>G | 5'Flank (SNP) | VAF 94/180 reads (52%) | catalogued as rs777340557; called by muse, mutect2, varscan2
- SGMS1 | chr10:50625109 T>C | 5'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as rs1266055957; called by muse, mutect2, varscan2
- SLC25A34 | c.*356G>A | 3'UTR (SNP) | VAF 61/141 reads (43%) | catalogued as rs998632373; called by muse, mutect2, varscan2
- SPAG16-DT | n.445T>G | RNA (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- SPIN4 | c.*1525A>T | 3'UTR (SNP) | VAF 31/33 reads (94%) | called by muse, mutect2, varscan2
- SYNGR1 | c.*261T>C | 3'UTR (SNP) | VAF 60/72 reads (83%) | called by muse, mutect2, varscan2
- SYNM | c.1007-78G>A | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- WDR17 | chr4:176180744 G>A | 3'Flank (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- ZDHHC12 | c.100+123C>T | Intron (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- ZNF148 | c.*1437T>C | 3'UTR (SNP) | VAF 43/155 reads (28%) | called by muse, mutect2, varscan2
- ZNF710 | c.*755dup | 3'UTR (INS) | VAF 62/275 reads (23%) | called by mutect2, pindel, varscan2
- ZNF84 | c.*3475C>T | 3'UTR (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
